Somatic mutation profile of tumor specimen MMRF_1641_1_BM_CD138pos (aliquot MMRF_1641_1_BM_CD138pos_T1_KBS5U_L04311) from MMRF case MMRF_1641, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 70.4 years (25,712 days).
Specimen MMRF_1641_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f322d8cf-f599-47aa-b2a1-2cb2000ea488.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1641_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1641_1_PB_Whole_C3_KBS5U_L04322; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1ffb2261-6008-48a2-b9d1-4208378cb519

The open-access MAF lists 115 somatic variants for this specimen: 44 protein-altering or splice-affecting, 18 silent, 53 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, 3'UTR 32, Silent 18, Intron 11, 5'UTR 6, Nonsense Mutation 4, RNA 2, Frame Shift Del 1, 5'Flank 1, Frame Shift Ins 1, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.559+1G>A p.X187_splice | Splice Site (SNP) | VAF 32/38 reads (84%) | hotspot (GDC flag); catalogued as rs1131691042, CS137624, COSV52670017, COSV52686439, COSV52695669; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANK1 | c.2815C>A p.P939T | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55900009; called by muse, mutect2, varscan2
- ANO3 | c.2839C>T p.R947* | Nonsense Mutation (SNP) | VAF 76/284 reads (27%) | catalogued as rs763228921, COSV56785203; called by muse, mutect2, varscan2
- B3GALNT1 | c.337C>T p.L113F | Missense Mutation (SNP) | VAF 54/167 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as COSV57580211; called by muse, mutect2, varscan2
- BMP2K | c.1694T>G p.L565R | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.691); catalogued as rs1332247167; called by muse, mutect2, varscan2
- C4orf54 | c.2237G>A p.R746H | Missense Mutation (SNP) | VAF 14/199 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.922); catalogued as rs878985096, COSV101552155; called by muse, mutect2
- COL6A5 | c.854C>T p.T285I | Missense Mutation (SNP) | VAF 87/293 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs867684833; called by muse, mutect2, varscan2
- DNAH5 | c.6556C>T p.R2186W | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756444637, COSV99451864; called by muse, mutect2, varscan2
- FAM110C | c.734C>A p.T245N | Missense Mutation (SNP) | VAF 44/77 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.223); catalogued as rs1339909541, COSV100566892; called by muse, mutect2, varscan2
- FLRT2 | c.589G>A p.D197N | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.553); catalogued as rs917154794, COSV58141463; called by muse, mutect2, varscan2
- HLA-DOA | c.253G>A p.G85R | Missense Mutation (SNP) | VAF 55/111 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs112121360; called by muse, mutect2, varscan2
- IGHV1-24 | c.61G>A p.V21I | Missense Mutation (SNP) | VAF 24/27 reads (89%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.455); catalogued as rs1555470261; called by muse, mutect2, varscan2
- IGHV2-70 | c.200A>G p.E67G | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs529165184; called by muse, varscan2
- IGHV2-70 | c.118A>G p.T40A | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs553609563; called by muse, varscan2
- KALRN | c.1228C>T p.R410C | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754572975, COSV53780874; called by muse, mutect2, varscan2
- LTB | c.200A>T p.Q67L | Missense Mutation (SNP) | VAF 68/146 reads (47%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs532757438; called by muse, mutect2, varscan2
- NTNG2 | c.763C>T p.R255W | Missense Mutation (SNP) | VAF 35/158 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV62366723; called by muse, mutect2, varscan2
- OR5AP2 | c.158T>C p.V53A | Missense Mutation (SNP) | VAF 56/209 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV57259222; called by muse, mutect2, varscan2
- PGPEP1L | c.142C>T p.Q48* | Nonsense Mutation (SNP) | VAF 25/76 reads (33%) | catalogued as COSV66709167; called by muse, mutect2, varscan2
- PRUNE2 | c.8725G>A p.G2909R | Missense Mutation (SNP) | VAF 61/113 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772474129, COSV56318019; called by muse, mutect2, varscan2
- RGL3 | c.722C>T p.P241L | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs1306770015; called by muse, mutect2, varscan2
- RYR3 | c.9763G>A p.A3255T (on ENST00000389232; = p.A3256T on NM_001036.6) | Missense Mutation (SNP) | VAF 63/247 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0.061); catalogued as rs772059314; called by muse, mutect2, varscan2
- SDR9C7 | c.811C>T p.R271W | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.099); catalogued as rs770439255, COSV53289577; called by muse, mutect2, varscan2
- SEC16A | c.1790C>T p.P597L | Missense Mutation (SNP) | VAF 40/157 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs56110017; called by muse, mutect2, varscan2
- SLC24A2 | c.980G>A p.R327H | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.731); catalogued as rs770762176, COSV53868415; called by muse, mutect2, varscan2
- SLC2A3 | c.932C>T p.A311V | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.93); PolyPhen probably damaging (0.941); catalogued as rs777935518; called by muse, mutect2, varscan2
- ZNF606 | c.1679G>A p.R560K | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.337); catalogued as COSV58705581; called by muse, mutect2, varscan2
- ARHGEF28 | c.4472G>A p.G1491D | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- C15orf39 | c.129dup p.K44Qfs*14 | Frame Shift Ins (INS) | VAF 26/109 reads (24%) | called by mutect2, pindel, varscan2
- CFAP53 | c.417G>C p.E139D | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- DCUN1D3 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 7/187 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.218); called by muse, mutect2
- ENTR1 | c.826G>C p.D276H (on ENST00000357365 / NM_001039707.2; = p.D253H on NM_006643.4) | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- IPO8 | c.1205C>T p.A402V | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.088); called by muse, mutect2
- JSRP1 | c.916T>G p.W306G | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- LAMA2 | c.7113T>G p.F2371L | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- LAMA2 | c.7931G>A p.R2644K | Missense Mutation (SNP) | VAF 42/75 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LRRC58 | c.690_691del p.E230Dfs*23 | Frame Shift Del (DEL) | VAF 54/193 reads (28%) | called by pindel, varscan2
- LRRFIP2 | c.688A>G p.I230V | Missense Mutation (SNP) | VAF 67/198 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- SETD2 | c.4685G>A p.W1562* | Nonsense Mutation (SNP) | VAF 52/195 reads (27%) | called by muse, mutect2, varscan2
- SLC15A4 | c.731A>G p.Q244R | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.75); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SPTBN5 | c.1906G>C p.E636Q | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- TAS2R41 | c.643C>T p.Q215* | Nonsense Mutation (SNP) | VAF 53/112 reads (47%) | called by muse, mutect2, varscan2
- TNKS1BP1 | c.4924G>T p.G1642W | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UTP6 | c.1526A>G p.D509G | Missense Mutation (SNP) | VAF 31/32 reads (97%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADGRG4 | c.2532A>G p.A844= | Silent (SNP) | VAF 16/200 reads (8%) | called by muse, mutect2
- BRD9 | c.1023G>A p.T341= | Silent (SNP) | VAF 28/103 reads (27%) | catalogued as rs778750397, COSV100057394; called by muse, mutect2, varscan2
- CATSPERB | c.3336A>G p.S1112= | Silent (SNP) | VAF 24/79 reads (30%) | catalogued as COSV56423850; called by muse, mutect2, varscan2
- CHL1 | c.759C>A p.L253= (on ENST00000397491 / NM_001253387.1; = p.L269= on NM_006614.4) | Silent (SNP) | VAF 17/80 reads (21%) | called by muse, mutect2, varscan2
- CNTNAP5 | c.3000T>C p.A1000= | Silent (SNP) | VAF 30/77 reads (39%) | called by muse, mutect2, varscan2
- EPB41L3 | c.198A>G p.E66= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as rs570957939; called by muse, mutect2, varscan2
- H3C3 | c.378G>A p.Q126= | Silent (SNP) | VAF 59/128 reads (46%) | catalogued as rs756634551; called by muse, mutect2, varscan2
- IGHV2-70 | c.126C>T p.T42= | Silent (SNP) | VAF 26/46 reads (57%) | catalogued as rs548315389; called by muse, varscan2
- IGLV4-60 | c.339T>C p.C113= | Silent (SNP) | VAF 75/84 reads (89%) | called by muse, varscan2
- KIF4A | c.3636G>A p.R1212= | Silent (SNP) | VAF 23/23 reads (100%) | called by muse, mutect2, varscan2
- MYOM3 | c.1023G>A p.G341= | Silent (SNP) | VAF 29/54 reads (54%) | catalogued as rs1374459585; called by muse, mutect2
- PCDHGB1 | c.1482G>A p.P494= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as rs772414660, COSV53917455; called by muse, mutect2, varscan2
- PIGF | c.249C>T p.C83= | Silent (SNP) | VAF 39/72 reads (54%) | called by muse, mutect2, varscan2
- PTPRF | c.5415G>A p.E1805= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as rs373191864; called by muse, mutect2, varscan2
- RGL2 | c.1870C>T p.L624= | Silent (SNP) | VAF 26/56 reads (46%) | catalogued as rs1378090640; called by muse, mutect2, varscan2
- RIMS2 | c.4566C>T p.I1522= (on ENST00000666250 / NM_001348490.2; = p.I1093= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as rs267601696, COSV51668205; called by mutect2, varscan2
- SIGLEC9 | c.1368C>T p.Y456= | Silent (SNP) | VAF 9/98 reads (9%) | called by muse, mutect2
- VPS13C | c.3381C>G p.A1127= (on ENST00000644861 / NM_020821.3; = p.A1084= on NM_017684.5) | Silent (SNP) | VAF 35/262 reads (13%) | called by muse, mutect2, varscan2
- ABCD2 | c.*2866G>A | 3'UTR (SNP) | VAF 50/118 reads (42%) | called by muse, mutect2, varscan2
- AC093536.1 | n.395C>A | RNA (SNP) | VAF 41/122 reads (34%) | called by muse, mutect2, varscan2
- AGBL1 | c.*111A>G | 3'UTR (SNP) | VAF 24/146 reads (16%) | called by muse, mutect2, varscan2
- AGXT2 | c.*102T>C | 3'UTR (SNP) | VAF 55/199 reads (28%) | called by muse, mutect2, varscan2
- AL441992.2 | c.*5216C>A | 3'UTR (SNP) | VAF 12/28 reads (43%) | called by muse, mutect2
- ASPH | c.*1914T>C | 3'UTR (SNP) | VAF 36/130 reads (28%) | called by muse, mutect2, varscan2
- ATL3 | c.*5133dup | 3'UTR (INS) | VAF 23/177 reads (13%) | called by mutect2, pindel, varscan2
- BMERB1 | c.*848C>T | 3'UTR (SNP) | VAF 19/51 reads (37%) | catalogued as rs11540893; called by muse, mutect2, varscan2
- CCNQP1 | n.236G>A | RNA (SNP) | VAF 15/89 reads (17%) | catalogued as rs766701983; called by muse, mutect2, varscan2
- CCNT1 | c.*3388G>C | 3'UTR (SNP) | VAF 4/61 reads (7%) | called by muse, mutect2
- CNTNAP5 | c.*921_*930del | 3'UTR (DEL) | VAF 18/40 reads (45%) | catalogued as rs150415382; called by mutect2, varscan2
- COL2A1 | c.293-10del | Intron (DEL) | VAF 39/96 reads (41%) | called by mutect2, pindel, varscan2
- DGKG | c.*549C>T | 3'UTR (SNP) | VAF 20/79 reads (25%) | called by muse, mutect2, varscan2
- EPS8L2 | c.895+62A>G | Intron (SNP) | VAF 9/41 reads (22%) | catalogued as rs772789126; called by muse, mutect2, varscan2
- FOXRED2 | chr22:36487688 C>G | 3'Flank (SNP) | VAF 7/33 reads (21%) | called by muse, mutect2, varscan2
- FOXRED2 | c.*1085G>A | 3'UTR (SNP) | VAF 9/48 reads (19%) | called by muse, varscan2
- FOXRED2 | c.*1056G>C | 3'UTR (SNP) | VAF 11/50 reads (22%) | called by muse, varscan2
- FYB2 | c.*597A>G | 3'UTR (SNP) | VAF 21/55 reads (38%) | called by muse, mutect2, varscan2
- GRIK4 | c.*468C>A | 3'UTR (SNP) | VAF 10/62 reads (16%) | called by muse, mutect2, varscan2
- H3C8 | c.*123dup | 3'UTR (INS) | VAF 18/50 reads (36%) | called by mutect2, pindel, varscan2
- IL21R | c.-17+506G>A | Intron (SNP) | VAF 39/107 reads (36%) | catalogued as rs1476959825; called by muse, mutect2, varscan2
- KCNH8 | c.812-10dup | Intron (INS) | VAF 42/114 reads (37%) | called by mutect2, varscan2
- LGR4 | c.-308G>A | 5'UTR (SNP) | VAF 22/50 reads (44%) | called by muse, mutect2, varscan2
- LIMCH1 | c.487-480A>C | Intron (SNP) | VAF 115/246 reads (47%) | called by muse, mutect2, varscan2
- LIPH | c.*469T>G | 3'UTR (SNP) | VAF 32/112 reads (29%) | called by muse, mutect2, varscan2
- LRPPRC | c.-12G>T | 5'UTR (SNP) | VAF 26/31 reads (84%) | catalogued as rs755338807; called by muse, varscan2
- MDM4 | c.*123T>A | 3'UTR (SNP) | VAF 24/51 reads (47%) | called by muse, mutect2, varscan2
- MFAP3L | c.*3449_*3452del | 3'UTR (DEL) | VAF 20/67 reads (30%) | catalogued as rs1482202060; called by pindel, varscan2
- MLEC | c.*623C>G | 3'UTR (SNP) | VAF 26/56 reads (46%) | called by muse, mutect2, varscan2
- NDUFS2 | c.-79T>A | 5'UTR (SNP) | VAF 16/32 reads (50%) | called by muse, mutect2, varscan2
- NIN | c.6079-1424T>C | Intron (SNP) | VAF 39/68 reads (57%) | called by muse, mutect2, varscan2
- NRK | c.*2464A>C | 3'UTR (SNP) | VAF 22/24 reads (92%) | called by muse, mutect2, varscan2
- OSBPL3 | c.*125G>A | 3'UTR (SNP) | VAF 25/79 reads (32%) | called by muse, mutect2, varscan2
- PCDH9 | c.*606_*607del | 3'UTR (DEL) | VAF 16/43 reads (37%) | called by pindel, varscan2
- PRKN | c.*2038T>G | 3'UTR (SNP) | VAF 16/25 reads (64%) | called by muse, mutect2, varscan2
- RCC1 | c.-153+50A>G | Intron (SNP) | VAF 18/50 reads (36%) | called by muse, mutect2, varscan2
- RNF152 | c.*7440T>C | 3'UTR (SNP) | VAF 10/35 reads (29%) | called by muse, mutect2, varscan2
- SERF1A | c.*103T>C | 3'UTR (SNP) | VAF 8/10 reads (80%) | called by mutect2, varscan2
- SH3TC2 | c.3478+429A>T | Intron (SNP) | VAF 28/135 reads (21%) | called by muse, mutect2, varscan2
- SP2 | c.*1127T>C | 3'UTR (SNP) | VAF 17/28 reads (61%) | catalogued as rs922058614; called by muse, mutect2, varscan2
- TCF21 | c.*720G>C | 3'UTR (SNP) | VAF 22/33 reads (67%) | called by muse, mutect2, varscan2
- TDRKH | c.-20G>C | 5'UTR (SNP) | VAF 9/166 reads (5%) | called by muse, mutect2
- TM4SF18 | c.*2829A>G | 3'UTR (SNP) | VAF 26/97 reads (27%) | called by muse, mutect2, varscan2
- TMCC3 | c.*1280G>T | 3'UTR (SNP) | VAF 37/90 reads (41%) | called by muse, mutect2, varscan2
- TMEM131 | c.1074+5850C>G | Intron (SNP) | VAF 17/44 reads (39%) | called by muse, mutect2, varscan2
- TMEM239 | c.*313G>A | 3'UTR (SNP) | VAF 39/88 reads (44%) | catalogued as rs750767282; called by muse, mutect2, varscan2
- TNS3 | chr7:47582557 C>T | 5'Flank (SNP) | VAF 99/106 reads (93%) | called by muse, mutect2, varscan2
- TOGARAM2 | c.2722+142T>G | Intron (SNP) | VAF 36/110 reads (33%) | catalogued as rs1489159508; called by muse, mutect2, varscan2
- TP53BP2 | c.996+73G>A | Intron (SNP) | VAF 22/42 reads (52%) | catalogued as rs925188805; called by muse, mutect2
- TRAF3 | c.*79C>T | 3'UTR (SNP) | VAF 39/83 reads (47%) | called by muse, mutect2, varscan2
- ZNF232 | c.-15C>G | 5'UTR (SNP) | VAF 49/54 reads (91%) | called by muse, mutect2, varscan2
- ZNF234 | c.*121C>G | 3'UTR (SNP) | VAF 4/31 reads (13%) | called by muse, mutect2
- ZNF606 | c.-135C>T | 5'UTR (SNP) | VAF 9/61 reads (15%) | catalogued as rs1173598909; called by muse, mutect2, varscan2
